MMRF case MMRF_1434 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2555ccf0-8d72-448b-a307-9718a457ddbc

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.8 years (22,582 days); ISS stage: II; Days to last known disease status: 1,372 days (3.8 years); Days to last follow up: 1,372 days (3.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 88 days; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days; Days to treatment end: 114 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 11 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.577 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 0.219 µg/mL; Lactate Dehydrogenase 6.25 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 11.7 mmol/L.
- Day 88 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.529 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0688 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 11.9 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 9.9 mmol/L.
- Day 205 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.123 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.081 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 9.4 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 9.57 mmol/L.
- Day 280 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.853 mg/dL; Immunoglobulin G 7.68 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 7.15 mmol/L.
- Day 353 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 8.29 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 7.76 mmol/L.
- Day 456 (ECOG 0): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.782 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.96 g/L; Beta 2 Microglobulin 2.27 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 7.7 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 11 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 638 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.943 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 1.23 g/L; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 8.14 mmol/L.
- Day 732 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.91 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 8.36 mmol/L.
- Day 823 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.685 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 4.77 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 9.13 mmol/L.
- Day 914 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.89 g/L; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 9.74 mmol/L.
- Day 1,001 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.92 mmol/L.
- Day 1,092 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 1.02 g/L; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 8.31 mmol/L.
- Day 1,183 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 1.19 g/L; Lactate Dehydrogenase 4.65 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.72 mmol/L.
- Day 1,281 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 8.47 mmol/L.
- Day 1,372 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 7.04 mmol/L.

Other clinical attributes
- Day 11: Weight: 123 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1434_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 11 days.
- Sample MMRF_1434_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 11 days.
